Somatic mutation profile of tumor specimen MP2PRT-PAVKPY-TMP1-A (aliquot MP2PRT-PAVKPY-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVKPY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.4 years (1,963 days).
Specimen MP2PRT-PAVKPY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03389caa-d829-41e3-8c52-d47d4d674288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKPY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKPY-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a6c6e5-17f4-4dca-be60-312f92d37d52

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A2 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760569641, COSV66415837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG1 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV65369060; called by muse, mutect2, varscan2
- PRR12 | c.1630C>T p.R544W (on ENST00000615927; = p.R1365W on NM_020719.3) | Missense Mutation (SNP) | VAF 96/319 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69816657; called by muse, mutect2, varscan2
- TAF1 | c.3610C>T p.R1204W (on ENST00000373790 / NM_138923.4; = p.R1225W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52107508; called by muse, mutect2, varscan2
- TPSD1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs142635848; called by muse, mutect2, varscan2
- ZNF90 | c.634A>G p.R212G | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.325); catalogued as rs782350995; called by muse, mutect2, varscan2
- IGHV1-58 | c.348_349insAGAAG p.A117Rfs*? | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by pindel, varscan2
- ITCH | c.1614G>A p.W538* (on ENST00000262650 / NM_001257137.3; = p.W497* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/229 reads (30%) | called by muse, mutect2, varscan2
- PDE3A | c.147C>A p.D49E | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM4 | c.90G>A p.P30= | Silent (SNP) | VAF 66/247 reads (27%) | catalogued as rs782380374, COSV55733249; called by muse, mutect2, varscan2
- CLEC18B | c.852C>T p.I284= | Silent (SNP) | VAF 29/399 reads (7%) | called by muse, mutect2, varscan2
- SYT14 | c.226+2534G>T | Intron (SNP) | VAF 72/153 reads (47%) | called by muse, mutect2, varscan2
